Somatic mutation profile of tumor specimen TCGA-2G-AALP-01A (aliquot TCGA-2G-AALP-01A-12D-A42Y-10) from TCGA case TCGA-2G-AALP, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 43.7 years (15,977 days).
Specimen TCGA-2G-AALP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e4c4050-ea00-4d74-9473-297983637959.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALP-10A (Blood Derived Normal), aliquot TCGA-2G-AALP-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9e763ed-f106-4939-85e2-114eb3115282

The open-access MAF lists 48 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 3, Frame Shift Del 2, Intron 2, 3'UTR 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA2 | c.910G>C p.G304R | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as CM112674, CM151296; called by muse, mutect2, varscan2
- FGL2 | c.1270T>C p.S424P | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs1477430333; called by muse, mutect2, varscan2
- IL18RAP | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51825778; called by muse, mutect2, varscan2
- INPP5D | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as rs1202108044; called by muse, mutect2, varscan2
- LCA5L | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as rs370952139; called by muse, mutect2, varscan2
- LRRTM4 | c.83C>G p.T28R | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV69138746, COSV69141749; called by muse, mutect2, varscan2
- PVRIG | c.630C>G p.S210R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs761744825; called by muse, varscan2
- RPLP0 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs751174993; called by muse, mutect2, varscan2
- ANAPC2 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CDK7 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CENPF | c.188C>G p.T63R | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CMTR1 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CSK | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FEZF1 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by mutect2, varscan2
- GRB10 | c.1178_1184del p.A393Dfs*50 (on ENST00000398812; = p.A347Dfs*50 on NM_001001549.3) | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- GSX2 | c.839_849del p.H280Lfs*4 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | called by mutect2, pindel, varscan2
- KRT38 | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRGUK | c.64A>T p.R22* | Nonsense Mutation (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- MDN1 | c.1763C>G p.T588R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MFSD13A | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MGAT3 | c.1135A>T p.I379F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MTF2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 55/191 reads (29%) | called by muse, mutect2, varscan2
- POLR3B | c.2605G>C p.V869L | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PORCN | c.851T>G p.L284R (on ENST00000326194 / NM_203475.3; = p.L273R on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PRMT8 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RASAL2 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 48/205 reads (23%) | called by muse, mutect2, varscan2
- SIN3B | c.1199G>T p.S400I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTBN5 | c.10847G>A p.G3616E | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ZBTB10 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZFYVE26 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- AC023055.1 | c.1470G>A p.R490= | Silent (SNP) | VAF 36/157 reads (23%) | called by muse, mutect2, varscan2
- ARAP3 | c.357C>T p.A119= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs200318347; called by muse, mutect2, varscan2
- CALCOCO1 | c.1404T>C p.S468= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- CD93 | c.330G>T p.P110= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV55666342, COSV55666974; called by muse, mutect2, varscan2
- FANCB | c.1344T>C p.P448= | Silent (SNP) | VAF 76/220 reads (35%) | catalogued as COSV60760671; called by muse, mutect2, varscan2
- JUP | c.2076C>T p.P692= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV60277986; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3603G>A p.G1201= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- NOS1 | c.4062T>C p.C1354= | Silent (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- PAX1 | c.1176G>T p.P392= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1195346294; called by muse, mutect2, varscan2
- PPP1R9A | c.330T>C p.D110= | Silent (SNP) | VAF 96/200 reads (48%) | called by muse, mutect2, varscan2
- RGSL1 | c.1329G>C p.P443= | Silent (SNP) | VAF 66/219 reads (30%) | called by muse, mutect2, varscan2
- SCG2 | c.222C>T p.S74= | Silent (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- SEMA5B | c.1050C>T p.G350= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs539416552; called by muse, mutect2, varscan2
- KRT74 | c.*4C>T | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+3455G>A | Intron (SNP) | VAF 17/66 reads (26%) | catalogued as rs1305076940; called by muse, mutect2, varscan2
- TGIF1 | c.-414G>A | 5'UTR (SNP) | VAF 37/76 reads (49%) | catalogued as COSV57907109; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439292 G>T | 3'Flank (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- WDFY3 | c.2345+11G>A | Intron (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
